Somatic mutation profile of tumor specimen TCGA-CZ-4853-01A (aliquot TCGA-CZ-4853-01A-01D-1429-08) from TCGA case TCGA-CZ-4853, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 82.7 years (30,191 days).
Specimen TCGA-CZ-4853-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f8aa4d0-2180-4f66-a486-197b991c5840.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-4853-11A (Solid Tissue Normal), aliquot TCGA-CZ-4853-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b142fb1e-381d-4b8c-a034-890430ac0390

The open-access MAF lists 109 somatic variants for this specimen: 84 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 23, Frame Shift Del 11, Nonsense Mutation 5, Frame Shift Ins 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs794726890, CD941806, CM023994, HM090060, COSV56545575, COSV56546439; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.3583C>T p.P1195S | Missense Mutation (SNP) | VAF 92/259 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.335); catalogued as rs1344564869, COSV61261787; called by muse, mutect2, varscan2
- ANAPC2 | c.1543T>A p.F515I | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60569771; called by muse, mutect2, varscan2
- AOC1 | c.2108C>G p.P703R | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV62868316, COSV62870841; called by muse, varscan2
- ARHGAP21 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as COSV57605223; called by muse, mutect2, varscan2
- BLM | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as COSV61923821; called by muse, mutect2, varscan2
- BRCA1 | c.3926A>T p.N1309I | Missense Mutation (SNP) | VAF 123/329 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as CD044104, COSV58789091; called by muse, mutect2, varscan2
- BRCA1 | c.3925A>C p.N1309H | Missense Mutation (SNP) | VAF 119/327 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV58789110; called by muse, mutect2, varscan2
- CCAR1 | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 131/334 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV56268900, COSV56269438; called by muse, mutect2, varscan2
- CCDC173 | c.1291G>T p.V431F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV71653349; called by muse, mutect2, varscan2
- CELSR2 | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV54770667; called by muse, mutect2, varscan2
- CFAP161 | c.839A>T p.D280V | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV54429100; called by muse, mutect2, varscan2
- CKAP2L | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 84/232 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV56696305; called by muse, mutect2, varscan2
- DCTN1 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.992); catalogued as COSV62620360; called by mutect2, varscan2
- DDX46 | c.1818C>A p.F606L | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.263); catalogued as COSV62799162; called by muse, mutect2, varscan2
- DNAAF4 | c.1251A>T p.E417D | Missense Mutation (SNP) | VAF 82/231 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV58248546; called by muse, mutect2, varscan2
- DOCK2 | c.2312G>T p.R771I | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV56955523; called by muse, mutect2, varscan2
- EAF2 | c.51del p.K18Sfs*2 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as COSV56544239; called by mutect2, pindel*, varscan2*
- EIF4G3 | c.3033A>T p.Q1011H | Missense Mutation (SNP) | VAF 148/363 reads (41%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.897); catalogued as COSV51680809; called by muse, mutect2, varscan2
- FOXB1 | c.301A>T p.S101C | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); catalogued as COSV68525780; called by muse, mutect2, varscan2
- FZD10 | c.1176C>A p.N392K | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs145130520, COSV57473351; called by muse, mutect2, varscan2
- FZD5 | c.1321G>C p.D441H | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.182); catalogued as rs754518625, COSV54943436; called by muse, mutect2, varscan2
- GLI2 | c.4610C>G p.P1537R (on ENST00000361492 / NM_001374353.1; = p.P1554R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/313 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as CM068649, COSV58040579; called by muse, mutect2, varscan2
- GNA13 | c.366G>C p.M122I | Missense Mutation (SNP) | VAF 115/316 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV71474683; called by muse, mutect2, varscan2
- GPC5 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as rs183780526, COSV65594610; called by muse, mutect2
- IL2RA | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.296); catalogued as COSV56920556; called by muse, mutect2, varscan2
- IQSEC3 | c.3071G>A p.R1024K (on ENST00000538872 / NM_001170738.2; = p.R721K on NM_015232.1) | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV58284198; called by muse, mutect2, varscan2
- JCAD | c.3412C>T p.P1138S | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as rs1470259810, COSV64759361; called by muse, mutect2, varscan2
- KAT6A | c.3449A>C p.K1150T | Missense Mutation (SNP) | VAF 178/524 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55905547, COSV55912553; called by muse, mutect2, varscan2
- KIAA0930 | c.256G>T p.D86Y (on ENST00000336156 / NM_001009880.2; = p.D91Y on NM_015264.2) | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV52662986; called by muse, mutect2, varscan2
- KIAA1522 | c.2731G>A p.A911T (on ENST00000373480 / NM_001198972.2; = p.A970T on NM_020888.3) | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53864124; called by muse, mutect2
- KIF13A | c.3076G>T p.G1026C | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52449177; called by muse, mutect2, varscan2
- KPNA4 | c.1195G>T p.G399* | Nonsense Mutation (SNP) | VAF 100/311 reads (32%) | catalogued as COSV62075476; called by muse, mutect2, varscan2
- LRP1 | c.9210G>A p.M3070I | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as COSV54509689; called by muse, mutect2, varscan2
- LRP2 | c.5395G>T p.G1799C | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55550996; called by muse, mutect2, varscan2
- LRRC4B | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as COSV101210167; called by muse, varscan2
- MACROD2 | c.1289A>T p.D430V (on ENST00000642719; = p.D402V on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as COSV53977394; called by muse, mutect2, varscan2
- METTL14 | c.1051A>T p.S351C | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV66310530; called by muse, mutect2, varscan2
- MOB2 | c.321C>A p.Y107* | Nonsense Mutation (SNP) | VAF 39/110 reads (35%) | catalogued as COSV100326639, COSV57318418; called by muse, mutect2, varscan2
- MRTFA | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62932970; called by muse, mutect2, varscan2
- MTBP | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV59962531; called by muse, mutect2, varscan2
- MVP | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.183); catalogued as rs3815823, COSV62421970; called by muse, mutect2, varscan2
- MYCL | c.898C>T p.R300* | Nonsense Mutation (SNP) | VAF 82/203 reads (40%) | catalogued as rs1218116984, COSV65693284; called by muse, mutect2, varscan2
- MYF6 | c.122T>A p.L41* | Nonsense Mutation (SNP) | VAF 48/154 reads (31%) | catalogued as COSV57351457; called by muse, varscan2
- MYH7B | c.3825G>C p.E1275D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52679209; called by muse, mutect2, varscan2
- NEXMIF | c.2078A>G p.D693G | Missense Mutation (SNP) | VAF 60/80 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV50028853; called by muse, mutect2, varscan2
- NF1 | c.6626T>C p.L2209S (on ENST00000358273 / NM_001042492.3; = p.L2188S on NM_000267.3) | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62201341; called by muse, mutect2, varscan2
- NKX2-2 | c.525G>C p.W175C | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65819461; called by muse, mutect2, varscan2
- PBRM1 | c.1853T>A p.L618H | Missense Mutation (SNP) | VAF 67/118 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56273210, COSV56313079; called by muse, mutect2, varscan2
- PIGB | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 104/256 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV51241538; called by muse, mutect2, varscan2
- PIK3R6 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.014); catalogued as COSV61002829; called by muse, mutect2, varscan2
- PLD4 | c.656T>C p.V219A | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV66915091; called by muse, mutect2, varscan2
- PRKD1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 114/294 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.339); catalogued as COSV59566973; called by muse, mutect2, varscan2
- PTDSS1 | c.1231C>A p.H411N | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV61264516; called by muse, mutect2, varscan2
- RGP1 | c.1135T>A p.Y379N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV65239415; called by muse, mutect2, varscan2
- RIC8B | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 86/225 reads (38%) | catalogued as COSV62694322; called by muse, mutect2, varscan2
- SEMA3C | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs373225376; called by muse, mutect2, varscan2
- SLC45A4 | c.1318T>C p.Y440H (on ENST00000517878 / NM_001286646.2; = p.Y389H on NM_001080431.2) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1440466413, COSV50137357; called by muse, mutect2, varscan2
- SLC5A12 | c.1703A>T p.E568V | Missense Mutation (SNP) | VAF 166/441 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV68448705; called by muse, mutect2, varscan2
- SOX8 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53509265; called by muse, mutect2, varscan2
- SPTA1 | c.995T>G p.L332R | Missense Mutation (SNP) | VAF 143/424 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV63752303; called by muse, mutect2, varscan2
- SSX5 | c.210C>A p.F70L (on ENST00000347757 / NM_175723.1; = p.F111L on NM_021015.4) | Missense Mutation (SNP) | VAF 70/112 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61254996; called by muse, mutect2, varscan2
- ST14 | c.1090A>T p.I364F | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV53832928; called by muse, mutect2, varscan2
- TBC1D31 | c.1579T>A p.C527S | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54865709; called by muse, mutect2, varscan2
- TLR8 | c.967T>A p.L323I (on ENST00000218032 / NM_138636.5; = p.L341I on NM_016610.4) | Missense Mutation (SNP) | VAF 111/162 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54317594; called by muse, mutect2, varscan2
- TMTC4 | c.1748A>G p.Y583C (on ENST00000376234 / NM_001350577.2; = p.Y602C on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294613057, COSV60892006; called by muse, mutect2, varscan2
- TNRC6A | c.3881C>T p.S1294F | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV59363584; called by muse, mutect2, varscan2
- TRAV26-1 | c.293G>C p.R98T | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs373469394; called by muse, mutect2, varscan2
- TUBG1 | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.976); catalogued as COSV99258560; called by muse, mutect2, varscan2
- VPS13C | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV51163346; called by muse, mutect2, varscan2
- WNK2 | c.6521T>C p.V2174A (on ENST00000297954 / NM_001282394.1; = p.V2137A on NM_006648.3) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV52940050; called by muse, mutect2, varscan2
- ZFP90 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 109/276 reads (39%) | SIFT tolerated (0.94); PolyPhen benign (0.09); catalogued as COSV68050887; called by muse, mutect2, varscan2
- C19orf44 | c.1483del p.L495Wfs*11 | Frame Shift Del (DEL) | VAF 70/228 reads (31%) | called by mutect2, pindel, varscan2
- CACHD1 | c.653del p.Y218Sfs*12 | Frame Shift Del (DEL) | VAF 50/189 reads (26%) | called by mutect2, pindel, varscan2
- CR1 | c.3686del p.G1229Afs*27 | Frame Shift Del (DEL) | VAF 87/296 reads (29%) | called by mutect2, pindel, varscan2
- HIC1 | c.1204del p.E402Rfs*51 (on ENST00000322941 / NM_001098202.1; = p.E383Rfs*51 on NM_006497.4) | Frame Shift Del (DEL) | VAF 5/8 reads (63%) | called by mutect2, varscan2
- HVCN1 | c.613_614insA p.R205Qfs*17 | Frame Shift Ins (INS) | VAF 18/76 reads (24%) | called by mutect2, pindel*, varscan2
- PCIF1 | c.1613+1del | Frame Shift Del (DEL) | VAF 47/164 reads (29%) | called by mutect2, pindel, varscan2
- PCSK6 | c.868_869del p.K290Vfs*33 | Frame Shift Del (DEL) | VAF 50/154 reads (32%) | called by mutect2, pindel, varscan2
- PRDM4 | c.521dup p.A175Cfs*8 | Frame Shift Ins (INS) | VAF 98/316 reads (31%) | called by mutect2, pindel, varscan2
- SCAF4 | c.2160_2166del p.P721Hfs*25 | Frame Shift Del (DEL) | VAF 30/117 reads (26%) | called by mutect2, pindel, varscan2
- SEPTIN4 | c.334_353delinsA p.L112Mfs*22 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | called by pindel, varscan2*
- SYNE2 | c.2448del p.Q817Kfs*12 | Frame Shift Del (DEL) | VAF 83/221 reads (38%) | called by mutect2, pindel*, varscan2
- TTN | c.19320_19321delinsG p.E6442Sfs*11 (on ENST00000591111; = p.E5515Sfs*11 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 69/317 reads (22%) | called by pindel, varscan2*
- ALS2 | c.2424C>T p.F808= | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as COSV51884335; called by muse, mutect2, varscan2
- BEST1 | c.720G>A p.V240= | Silent (SNP) | VAF 102/213 reads (48%) | catalogued as COSV57120560; called by muse, mutect2, varscan2
- BICD1 | c.2691C>A p.G897= | Silent (SNP) | VAF 74/237 reads (31%) | catalogued as COSV55674815, COSV55678324; called by muse, mutect2, varscan2
- BMP2K | c.2028T>C p.D676= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV55009486; called by muse, mutect2, varscan2
- CCNF | c.156C>T p.I52= | Silent (SNP) | VAF 44/141 reads (31%) | catalogued as COSV53539764; called by muse, mutect2, varscan2
- CPD | c.1704G>C p.V568= | Silent (SNP) | VAF 40/145 reads (28%) | catalogued as COSV56712497; called by muse, mutect2, varscan2
- CXCL10 | c.108T>C p.S36= | Silent (SNP) | VAF 71/180 reads (39%) | catalogued as COSV60660963; called by muse, mutect2, varscan2
- EFCAB12 | c.1224G>A p.P408= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs768748187, COSV58176102; called by mutect2, varscan2
- FAT3 | c.8007G>T p.L2669= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV53104038, COSV53147183; called by muse, mutect2, varscan2
- GNPTAB | c.393A>G p.T131= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV54779304; called by muse, mutect2, varscan2
- IPO9 | c.2748G>A p.K916= | Silent (SNP) | VAF 64/169 reads (38%) | catalogued as COSV64233524; called by muse, mutect2, varscan2
- MTMR11 | c.1671C>G p.P557= (on ENST00000439741 / NM_001145862.2; = p.P485= on NM_181873.3) | Silent (SNP) | VAF 37/142 reads (26%) | catalogued as COSV54965242; called by muse, mutect2, varscan2
- MYF6 | c.51G>T p.G17= | Silent (SNP) | VAF 42/138 reads (30%) | catalogued as COSV57351443, COSV57352033; called by muse, varscan2
- OPRPN | c.444C>T p.T148= | Silent (SNP) | VAF 80/218 reads (37%) | catalogued as rs767152161, COSV68192648; called by muse, varscan2
- PABPC3 | c.213C>G p.T71= | Silent (SNP) | VAF 58/135 reads (43%) | catalogued as rs769090460, COSV55799842; called by muse, mutect2, varscan2
- PCDHB8 | c.1932G>A p.L644= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as COSV50764273, COSV99175964; called by muse, mutect2, varscan2
- PIGT | c.1038C>T p.A346= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs141166012, COSV54126036; called by muse, mutect2, varscan2
- RAD51AP2 | c.2268A>T p.V756= | Silent (SNP) | VAF 69/195 reads (35%) | catalogued as COSV67587902; called by muse, mutect2, varscan2
- RPUSD2 | c.921G>T p.V307= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as COSV59765424; called by muse, mutect2, varscan2
- SHROOM4 | c.33C>T p.V11= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as COSV56788416; called by muse, mutect2, varscan2
- SPAG7 | c.462T>A p.P154= | Silent (SNP) | VAF 58/194 reads (30%) | catalogued as COSV52777184; called by muse, mutect2, varscan2
- SYCN | c.315C>A p.A105= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs990382684, COSV59212475; called by muse, mutect2, varscan2
- TTC1 | c.147T>C p.D49= | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as COSV51464788; called by muse, mutect2, varscan2
- KCNU1 | c.2010-17182C>A | Intron (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- NBPF25P | n.1384T>C | RNA (SNP) | VAF 170/583 reads (29%) | called by muse, mutect2, varscan2
